Somatic mutation profile of tumor specimen 0DWES6 from CCDI case PBCNDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.4 years (5,982 days).
Specimen 0DWES6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59ecffff-298b-4b34-9a46-0ccdd0188deb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWERX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b7e987b-c8f7-47d3-b3ec-879eff6ab666

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Nonsense Mutation 2, Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCBLD1 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 266/898 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs760566526, COSV51641991; called by muse, mutect2, varscan2
- NOSIP | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 304/1231 reads (25%) | called by muse, mutect2, varscan2
- ZNF484 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 34/676 reads (5%) | called by muse, mutect2
- CFH | c.619+46A>T | Intron (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- HECTD3 | c.1238+72G>A | Intron (SNP) | VAF 16/258 reads (6%) | catalogued as rs954008011; called by muse, mutect2
- PCYT2 | c.-4G>A | 5'UTR (SNP) | VAF 100/356 reads (28%) | called by muse, mutect2, varscan2
- PSMA1 | c.415-51T>G | Intron (SNP) | VAF 124/401 reads (31%) | catalogued as rs1189320648; called by muse, mutect2, varscan2
